Gene-level copy-number profile of tumor specimen CUPP-B4JM-TTM1-A from CCG case CUPP-B4JM, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage IV; Age at diagnosis: 72.5 years (26,494 days).
Specimen CUPP-B4JM-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7384d0cd-3f83-4b7e-b2ef-40b1c4854810.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B4JM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/e22ad45d-89a7-4dd4-8f13-673cffa323ce

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 19; copy number 2: 3,830; copy number 3: 15,091; copy number 4: 22,051; copy number 5: 10,817; copy number 6: 2,417; copy number 7: 2,506; copy number 8: 82; copy number 9: 21; copy number 10: 58; copy number 11: 1,493.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:161,581,339–161,678,654, 6 genes (within-gene range 0–4): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1.
- chr5:710,355–850,986, 4 genes (within-gene range 0–2): ZDHHC11B, BRD9P2, ZDHHC11, SPCS2P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,572 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:39,106,990–40,353,133, 21 genes, copy number 9: ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT.
- chr8:41,929,479–145,066,685, 1,551 genes, copy number 10–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
